Somatic mutation profile of tumor specimen TARGET-20-PARVXT-09A (aliquot TARGET-20-PARVXT-09A-01D) from TARGET case TARGET-20-PARVXT, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.6 years (3,133 days).
Specimen TARGET-20-PARVXT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cf53389-e763-4dc2-aaa8-1b1d17cb5dd2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARVXT-14A (Bone Marrow Normal), aliquot TARGET-20-PARVXT-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada9d6a1-28a2-425f-aa28-4044c7901fb8

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.2216del p.G739Vfs*60 | Frame Shift Del (DEL) | VAF 60/181 reads (33%) | called by pindel*, varscan2
- WT1 | c.812dup p.V272Gfs*26 | Frame Shift Ins (INS) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
